Somatic mutation profile of tumor specimen TCGA-DX-A48K-01A (aliquot TCGA-DX-A48K-01A-11D-A307-09) from TCGA case TCGA-DX-A48K, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 65.0 years (23,756 days).
Specimen TCGA-DX-A48K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b03105f-7f56-4370-9985-1ba81b8e67c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A48K-10A (Blood Derived Normal), aliquot TCGA-DX-A48K-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ff95583-7b3e-4db9-ab3a-38831dadb818

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, In Frame Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC005324.2 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV100371960; called by muse, mutect2, varscan2
- C4orf33 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV99828959; called by muse, mutect2, varscan2
- DUOXA2 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs891119037, COSV99973283; called by muse, mutect2, varscan2
- GLUL | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs1233603258, COSV59382805; called by muse, mutect2, varscan2
- MAP2K7 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV101209071; called by muse, mutect2, varscan2
- OPCML | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs372641813; called by muse, mutect2, varscan2
- PCDHA2 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.797); catalogued as rs782245079, COSV65370325; called by muse, mutect2, varscan2
- PCNX1 | c.3889T>A p.Y1297N | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99455995, COSV99456865; called by muse, mutect2, varscan2
- PYCR1 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs776048761, COSV100321564; called by muse, mutect2, varscan2
- RNF183 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as COSV99938095; called by muse, mutect2, varscan2
- SIRT3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100728841; called by muse, mutect2, varscan2
- SLC19A1 | c.565T>A p.S189T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.984); catalogued as COSV100229412; called by muse, mutect2, varscan2
- TEKT3 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV100107147; called by muse, mutect2
- TEX37 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs749136979, COSV100304633; called by muse, mutect2, varscan2
- TLR2 | c.2297T>C p.M766T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99472382; called by muse, mutect2, varscan2
- TNFRSF9 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1168985588, COSV66348925, COSV66349244; called by muse, mutect2, varscan2
- ZNF391 | c.493T>C p.Y165H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99772671; called by muse, mutect2, varscan2
- MYH7 | c.5228_5230del p.E1743del | In Frame Del (DEL) | VAF 12/51 reads (24%) | called by pindel, varscan2
- POM121C | c.2611A>T p.T871S (on ENST00000607367; = p.T629S on NM_001099415.3) | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SLC25A36 | c.845_850del p.R282_G283del (on ENST00000324194 / NM_001104647.3; = p.R281_G282del on NM_018155.3) | In Frame Del (DEL) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- CSMD1 | c.4257C>T p.D1419= (on ENST00000520002; = p.D1418= on NM_033225.6) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100149513; called by muse, mutect2, varscan2
- DNAH9 | c.12015G>A p.Q4005= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV99306357; called by muse, mutect2
- FAM118A | c.201G>A p.E67= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99343610; called by muse, mutect2, varscan2
- ZNF416 | c.534G>A p.K178= | Silent (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- PLEKHA8P1 | n.1594G>A | RNA (SNP) | VAF 12/94 reads (13%) | catalogued as rs145353585; called by muse, mutect2, varscan2
